Gene-level copy-number profile of tumor specimen TCGA-2G-AAK7-01A from TCGA case TCGA-2G-AAK7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 32.0 years (11,684 days).
Specimen TCGA-2G-AAK7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file af0efe7d-da0e-44b7-9e29-e3ff71c9b086.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAK7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,925 have no estimate.
https://portal.gdc.cancer.gov/files/dc16a424-027c-4ef1-ae98-c39e8875e377

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,503; copy number 2: 9,553; copy number 3: 23,339; copy number 4: 19,908; copy number 5: 1,467; copy number 6: 923; copy number 7: 363; copy number 8: 291; copy number 9: 548; copy number 10: 266; copy number 11: 181; copy number 12: 73; copy number 13: 16; copy number 14: 44; copy number 15: 47; copy number 20: 20; copy number 22: 4; copy number 25: 37; copy number 27: 8; copy number 30: 4; copy number 32: 17; copy number 33: 24; copy number 35: 60; copy number 37: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,897 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–42,058,517, 670 genes, copy number 7–12 (broad region; genes not listed).
- chr4:54,376,002–57,207,459, 69 genes, copy number 20–27 (broad region; genes not listed).
- chr12:9,852,984–32,993,754, 467 genes, copy number 7–37 (broad region; genes not listed).
- chr12:45,014,672–48,500,961, 103 genes, copy number 7–10 (broad region; genes not listed).
- chr12:50,112,197–51,271,362, 42 genes, copy number 7–8 (within-gene range 6–8): AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP.
- chr12:61,708,259–74,728,851, 245 genes, copy number 11–15 (broad region; genes not listed).
- chr14:64,503,712–76,283,103, 296 genes, copy number 9–10 (within-gene range 2–10) (broad region; genes not listed).
- chr15:55,056,723–55,319,113, 5 genes, copy number 7 (within-gene range 6–7): AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2.

Autosomal genes at a single copy (total copy number 1): 595. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
